Somatic mutation profile of tumor specimen BA3341D (aliquot aq-BA3341D) from BEATAML1.0 case 2628, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.9 years (22,983 days).
Specimen BA3341D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25abf198-af3a-41c8-9c0c-784232d4ea65.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3378D (Solid Tissue Normal), aliquot aq-BA3378D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ec73498-7fda-4f60-9e0d-a88c6020f3df

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 69/167 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- CDK13 | c.2871dup p.R958Sfs*19 | Frame Shift Ins (INS) | VAF 52/179 reads (29%) | called by mutect2, pindel, varscan2
- DLG3 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IRS1 | c.3315C>T p.S1105= | Silent (SNP) | VAF 56/131 reads (43%) | catalogued as rs749508598; called by muse, mutect2, varscan2
